Somatic mutation profile of tumor specimen C3L-01039-03 (aliquot CPT0170340034) from CPTAC case C3L-01039, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 59.5 years (21,733 days).
Specimen C3L-01039-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18d5597d-3c36-496b-acfe-d7579c0856fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01039-31 (Blood Derived Normal), aliquot CPT0167240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c7f27da-746a-4ece-947e-551d950263d1

The open-access MAF lists 29 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, Intron 4, Nonsense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 33/377 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- ATP12A | c.1573G>C p.A525P | Missense Mutation (SNP) | VAF 19/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs967156411; called by muse, mutect2
- CDH12 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as rs1291430724, COSV66409369; called by muse, mutect2
- CDH7 | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.202); catalogued as COSV59892387; called by muse, mutect2
- COL3A1 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.431); catalogued as rs762028131, COSV58584897; ClinVar: uncertain significance; called by muse, mutect2
- COL6A6 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756106307, COSV62016664, COSV62040144; called by muse, mutect2, varscan2
- GNL3L | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.283); catalogued as rs778008701; called by muse, mutect2, varscan2
- GPR158 | c.3082C>T p.H1028Y | Missense Mutation (SNP) | VAF 17/422 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1389889915; called by muse, mutect2
- IPO7 | c.3017A>G p.H1006R | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.093); catalogued as rs1431641189; called by muse, mutect2
- KBTBD3 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1232867103; called by muse, mutect2
- MYLK | c.4439G>A p.R1480Q | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs1397757032, COSV60609666; called by muse, mutect2
- NLRP2 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 24/558 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs540940476; called by muse, mutect2
- SLITRK2 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1556944777, COSV59422879; called by muse, mutect2, varscan2
- TGFBR2 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 23/487 reads (5%) | catalogued as CM076559, COSV55451791; called by muse, mutect2
- PLEKHN1 | c.1915A>T p.T639S (on ENST00000379409; = p.T587S on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- RECQL | c.1072A>T p.R358* | Nonsense Mutation (SNP) | VAF 7/190 reads (4%) | called by muse, mutect2
- BACH2 | c.1779C>T p.S593= | Silent (SNP) | VAF 38/674 reads (6%) | catalogued as rs373751160; called by muse, mutect2
- CBLB | c.1398C>T p.N466= | Silent (SNP) | VAF 31/684 reads (5%) | catalogued as rs56009631; called by muse, mutect2
- EPPK1 | c.6336G>A p.V2112= | Silent (SNP) | VAF 12/250 reads (5%) | catalogued as COSV73261802; called by muse, mutect2
- FREM3 | c.4878C>T p.D1626= | Silent (SNP) | VAF 15/435 reads (3%) | catalogued as rs997227800; called by muse, mutect2
- OR4C12 | c.705C>G p.L235= | Silent (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- PCDHGA8 | c.381C>T p.N127= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as rs770162660, COSV53918941; called by muse, mutect2
- SMIM17 | c.291C>G p.V97= | Silent (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- UGT2B17 | c.1015A>C p.R339= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- GASK1B | c.910+42T>C | Intron (SNP) | VAF 16/376 reads (4%) | called by muse, mutect2
- KCNK16 | c.803-57C>A | Intron (SNP) | VAF 30/396 reads (8%) | called by muse, mutect2
- SIGIRR | c.1069+107T>G | Intron (SNP) | VAF 17/289 reads (6%) | called by muse, mutect2
- THAP7 | chr22:21002647 T>C | 5'Flank (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- ZMIZ1 | c.957+479G>T | Intron (SNP) | VAF 9/267 reads (3%) | called by muse, mutect2
